Gene-level copy-number profile of tumor specimen C3N-00560-02 from CPTAC case C3N-00560, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 55.8 years (20,372 days).
Specimen C3N-00560-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ffdd36ee-827c-4bde-a085-bc2a4a79a12d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00560-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/4bf78e34-8a43-4a3e-928a-a946f2c443c8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 671; copy number 2: 23,907; copy number 3: 15,183; copy number 4: 15,258; copy number 5: 1,603; copy number 6: 1,194; copy number 7: 647; copy number 8: 120; copy number 9: 94; copy number 10: 180; copy number 11: 1; copy number 12: 4; copy number 14: 1; copy number 29: 1.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,906,757–89,907,246, 1 gene: IGKV3D-34.
- chr2:90,159,840–90,160,335, 1 gene (within-gene range 0–5): IGKV1D-12.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–3): BNIP3P22, AC008554.1, BNIP3P23.
- chr19:22,902,538–23,291,017, 21 genes: AC022145.1, AC022145.2, ZNF728, BNIP3P36, LINC01859, LINC01858, AC074135.2, AC074135.1, ZNF730, BNIP3P37, AC124856.1, SNX6P1, AC092329.2, ZNF724, AC092329.3, BNIP3P38, IPO5P1, AC092329.1, AC092329.4, VN1R90P, VN1R91P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,335 genes in 63 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–522,928, 31 genes, copy number 5: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:59,974,757–71,081,289, 173 genes, copy number 5 (broad region; genes not listed).
- chr1:205,302,063–205,532,793, 9 genes, copy number 6: NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1, MIR135B, LEMD1-DT, CDK18.
- chr1:234,356,704–234,593,402, 9 genes, copy number 6: AL355472.1, AL355472.2, AL355472.3, COA6-AS1, COA6, TARBP1, LINC01354, AL161640.1, U8.
- chr2:23,748,664–25,878,487, 48 genes, copy number 5 (within-gene range 3–5): ATAD2B, PGAM1P6, RPS13P4, UBXN2A, SDHCP3, RN7SL610P, MFSD2B, WDCP, RNU6-370P, FKBP1B, SF3B6, FAM228B, TP53I3, PFN4, AC008073.3, AC008073.2, FAM228A, AC008073.1, ITSN2, AC009228.1, AC009228.2, HMGN2P20, RPL36AP13, NCOA1, RNA5SP88, RNU6-936P, PTRHD1, CENPO, ADCY3, AC012073.1, DNAJC27, RPS13P5, SNORD14, DNAJC27-AS1, AC013267.1, Y_RNA, EFR3B, RN7SL856P, SUCLA2P3, POMC, LINC01381, DNMT3A, MIR1301, ARNILA, DTNB, DTNB-AS1, Y_RNA, ASXL2.
- chr2:98,761,098–101,024,032, 39 genes, copy number 6 (within-gene range 4–6): LINC02611, RNU4-84P, CRACDL, RNU7-46P, TSGA10, SMC3P1, AC079447.1, C2orf15, LIPT1, AC092587.1, MITD1, MRPL30, LYG2, LYG1, TXNDC9, EIF5B, REV1, AC018690.1, AFF3, AC092667.1, LINC01104, LONRF2, CYCSP7, AC012493.1, CHST10, RALBP1P2, NMS, ARPP19P2, PDCL3, HMGN2P22, LINC01849, NANOGNBP1, LINC01868, AC092168.1, NPAS2, AC092168.2, NPAS2-AS1, AC016738.1, RPL31.
- chr4:149,351,709–151,027,617, 16 genes, copy number 5: IQCM, AC108168.1, AC093893.1, AKIRIN2P1, RNA5SP167, RNU6-1230P, AC105343.1, DCLK2, RNU7-194P, LRBA, AC092612.1, AC110813.1, MAB21L2, ZBTB8OSP1, RNA5SP168, AK4P6.
- chr5:58,198–45,895,970, 679 genes, copy number 5–12 (broad region; genes not listed).
- chr6:391,752–10,930,423, 198 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr6:42,564,029–42,963,880, 14 genes, copy number 6 (within-gene range 3–6): UBR2, RNU6-890P, PRPH2, ATP6V0CP3, TBCC, BICRAL, RPL7L1, C6orf226, PTCRA, AL035587.2, CNPY3, AL035587.1, RPL24P4, GNMT.
- chr7:11,820,317–13,872,513, 20 genes, copy number 6: THRAP3P3, TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1.
- chr7:115,833,273–117,715,971, 49 genes, copy number 6 (within-gene range 4–6): Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1.
- chr7:132,784,870–135,510,127, 36 genes, copy number 6: CHCHD3, AC009365.3, AC008038.1, MIR3654, RNU6-92P, ST13P7, EXOC4, MIR6133, AC083875.1, COX5BP3, RPS3AP27, LRGUK, AC008154.2, SLC35B4, AC008154.1, AC009275.1, AKR1B1, AKR1B10, AKR1B15, BPGM, AC009276.1, TUBB3P2, CALD1, AC083870.1, AGBL3, CYREN, RNF14P4, TMEM140, AC083862.1, WDR91, AC009542.1, MIR6509, STRA8, SLC23A4P, CNOT4, SDHDP2.
- chr7:137,721,985–139,308,236, 36 genes, copy number 5–6: AC009245.1, CREB3L2, CREB3L2-AS1, AKR1D1, AC009263.1, AC024082.1, AC024082.2, RN7SKP223, RCC2P3, MIR4468, AC083867.2, Y_RNA, AC083867.1, AC008155.1, PTMAP10, IMPDH1P3, TRIM24, RPS3AP28, SVOPL, AC013429.2, AC013429.1, AC020983.1, UQCRFS1P2, ATP6V0A4, TMEM213, KIAA1549, RNU6-1272P, ZC3HAV1L, ZC3HAV1, AC018644.1, TTC26, AC009220.2, AC009220.3, AC009220.1, MZT1P2, UBN2.
- chr8:51,257,688–58,272,450, 111 genes, copy number 6–8 (broad region; genes not listed).
- chr8:59,557,528–84,921,844, 358 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:141,055,290–145,066,685, 187 genes, copy number 5 (broad region; genes not listed).
- chr9:129,007,036–129,753,042, 29 genes, copy number 5 (within-gene range 4–5): SH3GLB2, MIGA2, DOLPP1, CRAT, AL158151.2, PTPA, AL158151.3, AL158151.4, IER5L, AL158151.1, AL161785.1, C9orf106, AL353803.5, LINC01503, RN7SL159P, AL353803.3, AL353803.2, AL353803.1, LINC00963, AL353803.4, AL391056.2, AL391056.1, NTMT1, C9orf50, ASB6, AL590369.1, PRRX2, PRRX2-AS1, PTGES.
- chr10:133,640,789–133,778,699, 18 genes, copy number 5: AGGF1P2, CLUHP5, DUX4L28, DUX4L25, DUX4L24, DUX4L23, DUX4L22, DUX4L21, DUX4L20, DUX4L29, DUX4L10, DUX4L11, DUX4L12, DUX4L13, DUX4L14, DUX4L15, RPL23AP60, BX322534.1.
- chr11:289,126–382,117, 14 genes, copy number 5: PGGHG, IFITM5, AC136475.6, IFITM2, AC136475.2, IFITM1, AC136475.1, IFITM3, AC136475.4, AC136475.8, AC136475.7, AC136475.5, AC136475.9, B4GALNT4.
- chr11:6,713,536–6,926,878, 11 genes, copy number 5 (within-gene range 2–5): GVINP1, GVINP2, OR2AG2, OR2AG1, OR6A2, AC087280.2, AC087280.1, OR10A5, OR10A2, OR10A4, OR2D2.
- chr12:111,686,053–113,017,751, 33 genes, copy number 5 (within-gene range 4–5): ACAD10, AC002996.1, ALDH2, MIR6761, MAPKAPK5-AS1, MAPKAPK5, RPS2P41, ADAM1A, ADAM1B, TMEM116, SLC25A3P2, AC004024.1, ERP29, AC073575.2, NAA25, MIR3657, AC073575.1, Y_RNA, TRAFD1, Y_RNA, HECTD4, MIR6861, AC004217.1, RN7SKP71, RPL7AP60, AC004217.2, RPL6, PTPN11, RPH3A, MIR1302-1, OAS1, AC004551.1, OAS3.
- chr13:88,978,447–90,535,080, 17 genes, copy number 6: GRPEL2P1, LINC00440, LINC01047, TRIM60P13, SP3P, LINC02336, LINC01040, LINC00353, RPL7L1P1, AL355821.1, PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049.
- chr13:97,434,169–99,957,167, 54 genes, copy number 6: RAP2A, AL442067.1, AL442067.2, PSMA6P4, AL359502.1, RPL7AP61, AL356580.1, IPO5, FTLP8, FARP1, RNF113B, RN7SKP8, MIR3170, AL445223.1, AL161896.1, FARP1-AS1, STK24, AL356423.1, STK24-AS1, NUS1P4, CYCSP35, CALM2P4, RN7SL60P, SLC15A1, DOCK9, DOCK9-AS1, AL161420.1, RPL7L1P12, RNU6-83P, DOCK9-DT, RPS6P23, UBAC2-AS1, GAPDHP22, UBAC2, RN7SKP9, H2AZP3, GPR18, GPR183, MIR623, HMGB3P4, CCR12P, TM9SF2, LINC01232, AL139035.1, LINC00449, LINC01039, CFL1P8, CLYBL, MIR4306, CLYBL-AS2, CLYBL-AS1, AL137139.1, AL137139.3, AL137139.2.
- chr15:74,598,500–74,873,365, 14 genes, copy number 6: CLK3, AC100835.2, AC100835.1, EDC3, CYP1A1, CYP1A2, CSK, MIR4513, LMAN1L, AC091230.1, CPLX3, ULK3, MIR6882, SCAMP2.
- chr16:11,555–57,669, 8 genes, copy number 5: DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3, POLR3K, SNRNP25.
- chr16:35,335,277–35,912,516, 55 genes, copy number 5: FRG2HP, RARRES2P9, AGGF1P9, C2orf69P4, LINC01566, FRG2GP, AGGF1P4, FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP, AC018558.5, RARRES2P8, AGGF1P7, C2orf69P1, C1QL1P1, KIF18BP1, AC092325.1, AC106785.1, RNA5SP406, RNA5SP407, RNA5SP408, RNA5SP409, LINC02167, RNA5SP410, RNA5SP411, RNA5SP412, RNA5SP413, RNA5SP414, RNA5SP415, RNA5SP416, RNA5SP417, RNA5SP418, RNA5SP419, RNA5SP420, RNA5SP421, RNA5SP422, RNA5SP423, AC106785.2, HMGN2P41, VN1R70P, AC116553.1, AC116553.2, PPP1R1AP2.
- chr17:20,491,323–21,002,276, 43 genes, copy number 5–8 (within-gene range 2–8): YWHAEP3, KRT16P5, KRT16P3, AC015818.7, KRT17P6, KRT17P7, AC015818.6, AC015818.2, AC015818.5, TBC1D3P3, AC015818.8, AC015818.1, AC015818.3, COTL1P2, AC015818.4, CDRT15L2, ZSWIM5P2, MEIS3P2, AC087499.3, AC087499.1, AC087499.4, LINC02088, AC087499.7, AC087499.5, AC087499.6, AC087499.2, RNFT1P3, HNRNPA1P19, OLA1P2, SCDP1, AC126365.1, AC126365.2, ABHD17AP6, CCDC144NL, AC090774.2, CCDC144NL-AS1, RNU6-1178P, RNASEH1P1, AC090774.1, SPECC1P2, AC107926.1, AC087393.3, AC087393.1.
- chr17:21,456,513–22,070,538, 15 genes, copy number 7: AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18, ABBA01006766.1, NCOR1P2.
- chr17:26,981,694–30,186,475, 177 genes, copy number 5 (broad region; genes not listed).
- chr17:30,238,741–30,527,592, 9 genes, copy number 5: AC104984.4, SNORD63, BLMH, RNU6-1267P, TMIGD1, Y_RNA, RNU6-990P, CPD, GOSR1.
- chr17:39,156,894–39,567,559, 13 genes, copy number 5: ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1.
- chr18:21,182,503–22,169,878, 29 genes, copy number 5 (within-gene range 3–5): EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1.
- chr19:29,268,976–30,957,192, 25 genes, copy number 5: AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1.
- chr19:32,025,808–40,090,938, 378 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr19:42,387,019–45,070,956, 130 genes, copy number 6–8 (broad region; genes not listed).
- chr20:20,970,448–24,446,314, 92 genes, copy number 5 (broad region; genes not listed).
- chr20:50,794,894–51,131,667, 11 genes, copy number 10: BCAS4, TMSB4XP6, ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1, AL121785.1, RPSAP1.
- chr20:63,956,704–64,327,972, 19 genes, copy number 6 (within-gene range 4–6): ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.
- chr22:25,742,144–28,008,581, 60 genes, copy number 6 (within-gene range 4–6): MYO18B, AL022329.3, MYO18B-AS1, Z98949.2, RN7SKP169, Z98949.1, LINC02559, AL022337.1, SEZ6L, SEZ6L-AS1, RNA5SP495, Z99714.1, ASPHD2, HPS4, SRRD, TFIP11, Z95115.1, TPST2, MIR548J, HMGB1P10, Z95115.2, CRYBB1, CRYBA4, ISCA2P1, MIAT, Z99774.5, Z99774.1, Z99774.4, Z99774.2, MIATNB, Z99774.3, LINC01422, Z97353.1, Z97353.2, AL008638.3, RNU6-1066P, AL008638.5, AL008638.4, AL008638.2, AL008638.6, AL008638.1, AL021153.1, LINC01638, AL020994.3, AL020994.1, LINC02554, AL020994.2, AL049536.1, AL050402.1, AL133456.1, AL121885.2, AL121885.3, AL121885.1, MN1, PITPNB, TTC28-AS1, AL031591.2, MIR3199-1, MIR3199-2, AL031591.1.

Autosomal genes at a single copy (total copy number 1): 670. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
